Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2N5, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2N5-01A (Primary Tumor).

IIHAA Discrepancy		☒

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1. RIGHT INFERIOR LYMPH NODE (BX.): BENIGN THYROID TISSUE.

2. THYROID (THYROIDECTOMY):

SPECIMEN TYPE:

Total thyroidectomy

1CB-0-3

carcinoma, papillary, follicular variant 8340/3

TUMOR SITE:

Right lobe

Site: thyroid, NOS C73.9 hw 8/18/11

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant

TUMOR SIZE:

Greatest dimension: 4.5 cm

FOCALITY:

Unifocal

LYMPH NODES:

None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: tumor >4cm limited to thyroid

REGIONAL LYMPH NODES:

pNX: Cannot be assessed

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 3 mm (anterior, posterior)

VENOUS/LYMPHATIC INVASION:

Absent

DR. [REDACTED] HAS REVIEWED THIS CASE AND CONCURS.

Source: NCI Genomic Data Commons file 6d6e1a23-2246-4f55-9cb4-07fbebfeedc1 (TCGA-ET-A2N5.ED2E0C13-EB17-4947-995A-C3CFDA4F71E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).